Somatic mutation profile of tumor specimen 0DUETR from CCDI case PBCLAD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,165 days).
Specimen 0DUETR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d3e613-ec15-4572-81d3-05ee0c9f039f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7ef8371-29ab-436e-8b32-ec258ab02c3c

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 8, Silent 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLRE1A | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 312/1005 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441187126, COSV100800306, COSV63748154; called by muse, mutect2, varscan2
- ELL | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 357/949 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs748628873, COSV53215893; called by muse, mutect2, varscan2
- LTF | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 164/1732 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs542125560; called by muse, mutect2
- MUC5B | c.6455C>T p.T2152I | Missense Mutation (SNP) | VAF 89/1880 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1342513218; called by muse, mutect2
- NLRP7 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 45/828 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100053211; called by muse, mutect2
- RYR3 | c.7411G>T p.A2471S (on ENST00000389232; = p.A2472S on NM_001036.6) | Missense Mutation (SNP) | VAF 383/1127 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.09); catalogued as rs371521091; called by muse, mutect2, varscan2
- TRIM42 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 204/2216 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1311230606, COSV53882690; called by muse, mutect2
- ZNF471 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1351032095; called by muse, mutect2
- AADAT | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 34/964 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2
- ABCB11 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 265/766 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D3 | c.663dup p.R222* | Frame Shift Ins (INS) | VAF 113/830 reads (14%) | called by mutect2, varscan2
- CCDC40 | c.980T>A p.L327Q | Missense Mutation (SNP) | VAF 369/1037 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 54/2016 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- OBSCN | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 178/2631 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.817); called by muse, mutect2
- OR4M1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 87/3732 reads (2%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- RASAL3 | c.1910C>A p.T637N | Missense Mutation (SNP) | VAF 395/1191 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RBM10 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 40/690 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZKSCAN7 | c.1651T>C p.Y551H | Missense Mutation (SNP) | VAF 38/988 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 24/832 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF845 | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 136/1577 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- HIVEP1 | c.1434G>A p.E478= | Silent (SNP) | VAF 61/1790 reads (3%) | called by muse, mutect2
- LAMB3 | c.24T>C p.C8= | Silent (SNP) | VAF 62/2272 reads (3%) | called by muse, mutect2
- PRPF3 | c.820C>T p.L274= | Silent (SNP) | VAF 312/3389 reads (9%) | called by muse, mutect2
- ABCA2 | c.4958-21C>T | Intron (SNP) | VAF 96/734 reads (13%) | catalogued as rs761136889; called by muse, mutect2, varscan2
- EIF4A1 | c.206-38G>A | Intron (SNP) | VAF 158/384 reads (41%) | called by muse, mutect2, varscan2
- FNDC4 | c.249+22C>T | Intron (SNP) | VAF 20/530 reads (4%) | catalogued as rs1241134238; called by muse, mutect2
- GUCY2D | c.*1G>A | 3'UTR (SNP) | VAF 65/1092 reads (6%) | called by muse, mutect2
- KLC1 | c.1650+31C>T | Intron (SNP) | VAF 113/1147 reads (10%) | catalogued as rs762056634; called by muse, mutect2
- MCM2 | c.2449-69C>A | Intron (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- MGAM2 | c.*9C>A | 3'UTR (SNP) | VAF 46/510 reads (9%) | called by muse, mutect2
- OS9 | c.481-34C>T | Intron (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- PKN1 | c.2153+62C>G | Intron (SNP) | VAF 214/604 reads (35%) | called by muse, mutect2
- PSME2 | c.82-57T>C | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
